Somatic mutation profile of tumor specimen 0DQS01 from CCDI case PBCFKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,218 days).
Specimen 0DQS01: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b45e371f-97a5-4be3-8fe0-13077eed734e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a07b765c-ca10-4690-86de-1468095abcb7

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'UTR 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 24/850 reads (3%) | catalogued as COSV59989381; called by muse, mutect2
- DNAH5 | c.11350G>A p.V3784M | Missense Mutation (SNP) | VAF 273/783 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs375636304; called by muse, mutect2, varscan2
- DOCK6 | c.4996T>C p.S1666P | Missense Mutation (SNP) | VAF 280/800 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99626163; called by muse, mutect2
- OR10H4 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs749272961, COSV59061323; called by muse, mutect2, varscan2
- PARP1 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 211/1085 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376334288, COSV64690218; called by muse, mutect2, varscan2
- RRBP1 | c.2378C>T p.T793M (on ENST00000377813 / NM_001365613.2; = p.T360M on NM_004587.3) | Missense Mutation (SNP) | VAF 26/669 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1300070055; called by muse, mutect2
- PCDH19 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 339/769 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF38 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 43/912 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- SUPT16H | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 74/1149 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2
- VWDE | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 249/566 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL7A1 | c.5559C>T p.D1853= | Silent (SNP) | VAF 191/400 reads (48%) | catalogued as rs776433840, COSV60396674; called by muse, mutect2, varscan2
- MRGPRE | c.921G>T p.L307= | Silent (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- PPARA | c.63C>T p.S21= | Silent (SNP) | VAF 428/853 reads (50%) | catalogued as rs766182953; called by muse, mutect2, varscan2
- ZXDA | c.1146C>T p.H382= | Silent (SNP) | VAF 353/847 reads (42%) | catalogued as rs1166860533; called by muse, mutect2, varscan2
- ACAP3 | c.-82G>T | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- ITGAD | c.-8G>T | 5'UTR (SNP) | VAF 303/660 reads (46%) | called by muse, mutect2, varscan2
- ITGAL | c.1993+49G>T | Intron (SNP) | VAF 26/496 reads (5%) | called by muse, mutect2
- MNX1 | c.-15G>A | 5'UTR (SNP) | VAF 142/301 reads (47%) | called by muse, mutect2, varscan2
- ZNF254 | c.253+536C>G | Intron (SNP) | VAF 172/386 reads (45%) | called by muse, mutect2, varscan2
